Surgical pathology report (de-identified scan), TCGA case TCGA-NP-A5GY, project TCGA-KICH (Kidney Chromophobe), tissue source site International Genomics Consortium, specimen TCGA-NP-A5GY-01A (Primary Tumor).

[page 1 of 3]
Patient:

Referring Physician:

Gender: F

Ref#:

Hosp#:

Patient Location:

Date of Service:

Date Received:

Inpatient

FINAL SURGICAL PATHOLOGY REPORT

Diagnosis:

RENAL MASS, LEFT LOWER POLE, PARTIAL NEPHRECTOMY:

- CHROMOPHOBE RENAL CELL CARCINOMA, NUCLEAR GRADE 2
- EOSINOPHILIC TYPE, 2.2 CM.
- RENAL PARENCHYMAL MARGIN FOCALLY POSITIVE.

PATHOLOGIC TUMOR STAGING SUMMARY:

- Histologic type and grade: Chromophobe renal cell carcinoma, eosinophilic type, nuclear grade 2 out of 4.
- Primary tumor: pT1a, 2.2 cm.
- Regional lymph nodes: NA.
- Distant metastasis: NA
- Pathologic stage: I.
- Margin status: R1, focally positive at renal parenchymal (resection) margin.
- Lymphovascular and perineural invasion: Not identified.

COMMENT: Intradepartmental consultation with [REDACTED] is obtained. The carcinoma focally involves inked-cauterized renal parenchymal margin. The diagnosis is called to [REDACTED]

ICDD-3

Carcinoma, renal cell
Chromophobe type 8317/3

Site: (L) Kidney NOS C64.9

QW 12/20/12

Case #:

[page 2 of 3]
Case # [REDACTED]

FINAL SURGICAL PATHOLOGY REPORT

Kidney Tumor Staging Information

Data derived from current specimen. Staging in accordance with or modified from AJCC Cancer Staging Handbook, 7th Ed, and CAP protocol.

Procedure:	Partial nephrectomy.
Specimen type:	Left lower pole partial nephrectomy.
Specimen laterality:	Left.
Tumor Features:	
Tumor size:	2.2 cm.
Tumor focality:	Unifocal.
Histologic type:	Chromophobe renal cell carcinoma, eosinophilic-type.
Histologic grade (Fuhrman nuclear grade):	Nuclear grade 2 out of 4.
Sarcomatoid features:	Absent.
Macroscopic extent of tumor:	Tumor limited to kidney.
Microscopic tumor extension:	Tumor limited to kidney.
Lymph Nodes:	N/A (none submitted).
Margins:	Margin involved by invasive carcinoma (renal parenchymal margin).
Pathologic tumor staging descriptors:	
Primary tumor (pT):	pT1a.
Regional lymph nodes (pN):	N/A.
Distant metastasis (pM):	N/A.
Margin status (R):	R1, renal parenchymal margin focally involved.
Pathologic stage:	I.
Pathologic findings in non-neoplastic kidney:	Patchy glomerulosclerosis and chronic inflammation.
Additional pathologic findings:	N/A.
Comment:	N/A.

Case # [REDACTED]

[page 3 of 3]
Patient:

Case #:

FINAL SURGICAL PATHOLOGY REPORT

Source of Specimen:

Left Renal Mass

Clinical History/Operative Dx:

Left renal mass

Gross Description:

The specimen is designated as left renal mass. Initially received in the fresh state for possible tumor bank studies is a 5 gram portion of renal tissue, 2.7 x 2.3 x 1.8 cm. The renal surface is raised, glistening, tense. The surgical margin is now marked blue and the renal capsule is marked green. Sectioning demonstrates a well-circumscribed, glistening, somewhat fleshy, pink and tan lesion, 2.2 x 1.8 x 1.6 cm. Centrally, the lesion demonstrates a softened hemorrhagic appearance over an area 1.8 x 0.8 x 0.7 cm. Representative portions of grossly viable tumor is submitted for tumor bank studies. The remainder of the specimen is entirely submitted for routine histology in A1-A4.

Microscopic Description:

The sections show an a thinly encapsulated neoplasm with central zone of hemorrhage. The neoplastic cells have abundant granular-eosinophilic cytoplasm, distinct perinuclear halos, occasional binucleation, foci with wrinkled nuclear membranes, and scant nuclear atypia (but with scattered small nucleoli). No lymphovascular or perineural invasion is seen. While most of the margin is negative (microscopically free with a thin fibrous capsule), there is focal involvement of the inked-cauterized margin. A panel of immunostains shows the tumor to have strong expression of CK7 and CK8/18, and rare cells with expression of CD10 (but to be negative for: CD15/CD117/Vimentin), which together with the morphology is consistent with a chromophobe renal cell carcinoma.

Case #

Page 3

REPRINT: Orig. printing on

move to Chromophobe

Source: NCI Genomic Data Commons file 3f18a4de-8696-4e75-9921-d4e286cfd5d3 (TCGA-NP-A5GY.EBA860C3-7252-43DC-BF10-6EB614FC9AD2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).